Gene-level copy-number profile of tumor specimen ALCH-B36E-TTP1-B from ALCHEMIST case ALCH-B36E, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.2 years (27,451 days).
Specimen ALCH-B36E-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0e9107f6-21e2-42ed-b8cb-aeac64d6a16b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B36E-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/446d5730-e7c8-4427-9e1c-1849af863f9e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 3,284; copy number 2: 55,339; copy number 3: 151; copy number 4: 33; copy number 5: 12; copy number 6: 1; copy number 7: 1; copy number 8: 1; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:911,435–921,016, 3 genes (within-gene range 0–2): AL645608.2, AL645608.4, LINC02593.
- chr1:1,275,223–1,309,609, 4 genes (within-gene range 0–2): LINC01786, SCNN1D, ACAP3, MIR6726.
- chr1:3,560,695–3,560,790, 1 gene (within-gene range 0–1): MIR551A.
- chr2:10,021,578–10,022,825, 1 gene: AC104794.4.
- chr2:232,857,270–232,878,708, 1 gene (within-gene range 0–2): SNORC.
- chr2:240,886,048–240,896,889, 1 gene: MAB21L4.
- chr3:195,094,588–195,096,057, 1 gene (within-gene range 0–2): XXYLT1-AS1.
- chr4:2,793,071–2,841,098, 1 gene: SH3BP2.
- chr5:100,375,700–100,389,938, 2 genes: AC113385.3, AC113385.2.
- chr5:177,456,608–177,474,401, 1 gene: DBN1.
- chr7:149,776,042–149,833,979, 1 gene: SSPOP.
- chr8:43,542,076–43,544,057, 1 gene: AC134698.2.
- chr9:135,693,407–135,704,498, 1 gene (within-gene range 0–1): SOHLH1.
- chr11:560,404–568,457, 3 genes (within-gene range 0–1): RASSF7, MIR210HG, MIR210.
- chr11:67,398,181–67,425,607, 3 genes (within-gene range 0–2): PPP1CA, TBC1D10C, CARNS1.
- chr11:67,642,555–67,650,730, 1 gene: ACY3.
- chr11:68,312,591–68,449,275, 1 gene: LRP5.
- chr11:71,473,503–71,473,568, 1 gene (within-gene range 0–2): MIR6754.
- chr12:57,194,504–57,194,576, 1 gene (within-gene range 0–2): MIR1228.
- chr12:57,243,453–57,251,188, 1 gene (within-gene range 0–2): STAC3.
- chr12:132,550,729–132,554,947, 1 gene (within-gene range 0–2): AC131212.3.
- chr14:73,237,497–73,274,640, 4 genes (within-gene range 0–2): PAPLN, AC004846.1, RNU6-419P, AC004846.2.
- chr15:25,172,635–25,180,578, 5 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6.
- chr15:25,204,357–25,209,999, 4 genes (within-gene range 0–2): SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22.
- chr15:73,319,859–73,368,958, 2 genes: HCN4, AC068397.2.
- chr15:74,843,730–74,873,365, 1 gene: SCAMP2.
- chr16:1,512,979–1,514,675, 1 gene (within-gene range 0–2): AL031705.1.
- chr16:70,661,667–70,665,836, 1 gene (within-gene range 0–2): AC020763.4.
- chr16:87,834,592–87,834,660, 1 gene (within-gene range 0–2): MIR6775.
- chr16:88,079,161–88,087,383, 1 gene (within-gene range 0–2): AC134312.4.
- chr16:88,088,041–88,100,985, 1 gene (within-gene range 0–2): AC134312.1.
- chr17:75,818,815–75,844,552, 2 genes (within-gene range 0–2): AC087289.1, UNC13D.
- chr17:78,971,238–78,979,947, 1 gene: LGALS3BP.
- chr19:49,580,646–49,591,004, 1 gene (within-gene range 0–2): PRRG2.
- chr21:14,007,134–14,020,725, 2 genes: PPP6R2P1, FRG2MP.
- chr22:18,855,621–18,858,640, 1 gene (within-gene range 0–8): BCRP7.
- chr22:29,720,003–29,731,833, 1 gene (within-gene range 0–2): CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:347,982–522,928, 8 genes, copy number 5: RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr2:91,617,160–91,659,972, 1 gene, copy number 7 (within-gene range 2–7): LSP1P4.
- chr12:6,477,714–6,480,207, 1 gene, copy number 5: AC005840.3.
- chr21:12,999,676–13,016,692, 1 gene, copy number 6: AP001464.1.
- chr21:46,161,148–46,184,476, 1 gene, copy number 5: SPATC1L.
- chr22:18,846,811–18,861,049, 1 gene, copy number 8 (within-gene range 0–8): AC008132.1.
- chr22:18,873,543–18,894,407, 2 genes, copy number 9: FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 455. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
